Somatic mutation profile of tumor specimen TARGET-10-PANXGD-09A (aliquot TARGET-10-PANXGD-09A-01D) from TARGET case TARGET-10-PANXGD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.2 years (3,011 days).
Specimen TARGET-10-PANXGD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfc2af16-3f49-4ea1-b1a2-e2ff29ef4e28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXGD-10A (Blood Derived Normal), aliquot TARGET-10-PANXGD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccf80ac3-5a10-4039-a373-973cf88fd685

The open-access MAF lists 50 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Intron 3, 3'UTR 2, 5'Flank 2, 5'UTR 2, RNA 2, 3'Flank 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199781071; called by muse, mutect2
- APOB | c.11330C>T p.S3777L | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.036); catalogued as CM920060; called by muse, mutect2, varscan2
- C12orf40 | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs1278887511; called by muse, mutect2, varscan2
- EP300 | c.4336T>C p.Y1446H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54331178, COSV54349021; called by muse, mutect2, varscan2
- LBR | c.1328C>T p.T443M | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs531565954, COSV55289043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEIS2 | c.307C>T p.P103S (on ENST00000561208 / NM_170675.5; = p.P90S on NM_002399.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV54944897; called by muse, mutect2, varscan2
- SLC25A25 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142204445; called by muse, mutect2, varscan2
- SYPL2 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs779303619, COSV63994903; called by muse, mutect2, varscan2
- ADAM23 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ADAMTS19 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CDCA2 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL4A6 | c.3638G>A p.G1213E | Missense Mutation (SNP) | VAF 86/94 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYGN | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DDX6 | c.686_697delinsGAGCTTCT p.L229Rfs*5 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2*
- FSIP2 | c.5609A>C p.K1870T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- KIF15 | c.770_771insA p.T258Dfs*13 | Frame Shift Ins (INS) | VAF 71/196 reads (36%) | called by mutect2, pindel, varscan2
- KIF5C | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NCKAP5 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- NLGN1 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA7 | c.2141C>T p.T714I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PRB3 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); called by muse, varscan2
- SHC2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- SHROOM1 | c.2489C>T p.S830F (on ENST00000378679 / NM_001172700.2; = p.S825F on NM_133456.2) | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SVEP1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TANK | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by muse, mutect2
- WDR3 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.5064C>T p.H1688= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs764448953, COSV58142107; called by muse, mutect2, varscan2
- ANKK1 | c.1818G>A p.L606= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs753990582; called by muse, mutect2, varscan2
- BNC1 | c.330C>T p.I110= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs760614383; called by muse, mutect2
- CPXM2 | c.942G>A p.L314= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV53871141; called by muse, mutect2
- LGI2 | c.867C>T p.V289= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV66122713, COSV66124044; called by muse, mutect2, varscan2
- NCOR1 | c.2917C>T p.L973= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- NCOR1 | c.2916C>T p.L972= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99250830; called by muse, mutect2, varscan2
- RORB | c.831C>T p.I277= (on ENST00000396204 / NM_001365023.1; = p.I266= on NM_006914.4) | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs981071632, COSV65339683; called by muse, mutect2, varscan2
- SETD1A | c.3757C>T p.L1253= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs760858068; called by muse, mutect2, varscan2
- STMN2 | c.429G>A p.K143= | Silent (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
- WBP1L | c.630C>T p.A210= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV64009811; called by muse, mutect2, varscan2
- AC023794.1 | chr12:54172087 C>T | 3'Flank (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- ANKS3 | c.492-99G>A | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as rs149584068; called by muse, varscan2
- ATP8A2 | c.1662+70T>C | Intron (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- CENPX | chr17:82022889 G>A | 5'Flank (SNP) | VAF 3/14 reads (21%) | catalogued as rs1416669893; called by muse, mutect2
- CEP170P1 | n.487G>A | RNA (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- FER1L4 | n.4325C>G | RNA (SNP) | VAF 32/37 reads (86%) | called by muse, mutect2, varscan2
- FOXP4-AS1 | chr6:41519392 G>A | 3'Flank (SNP) | VAF 8/63 reads (13%) | catalogued as rs1024800937; called by muse, mutect2, varscan2
- GNL1 | c.-114C>T | 5'UTR (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- KRTAP19-2 | c.*85G>A | 3'UTR (SNP) | VAF 11/78 reads (14%) | catalogued as rs1031893330; called by muse, mutect2
- LEPR | c.*4C>T | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- PLPP2 | c.717+49C>T | Intron (SNP) | VAF 7/12 reads (58%) | catalogued as rs1471542982; called by muse, mutect2, varscan2
- PNO1 | chr2:68157807 C>T | 5'Flank (SNP) | VAF 36/127 reads (28%) | called by muse, mutect2, varscan2
- SRGAP3 | c.-119A>C | 5'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
